Surgical pathology report (de-identified scan), TCGA case TCGA-29-1777, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1777-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1777

Surg Path**CLINICAL HISTORY:**

Abdominal pelvic swelling.

GROSS EXAMINATION:

A. "Omentum (AF1)", received fresh for frozen section is a 14 x 8 x 4 cm segment of yellow-tan omentum with innumerable studded tumor nodules throughout. A piece has been previously submitted as frozen section AF1 and the remnant is submitted in block A1. Additional sections are submitted in block A2.

B. "Omentum", received fresh and placed in formalin is an 11 x 7 x 2.5 cm segment of yellow-tan omentum with innumerable tumor nodules throughout. Representative sections submitted in block B1.

C. "Right ovary". Received fresh is an adnexal specimen consisting of a 26.3 gram, 2 x 0.6 x 0.6 cm ovary and attached 4 x 0.2 cm fimbriated fallopian tube. The cut surface in the ovary is homogeneous, white-tan. Attached to the adnexal tissue is a 3 x 3 x 2 cm mass of tumor and soft tissue adhesions. Representative tube and ovary are submitted in block C1 and representative tumor submitted in block C2.

D. "Left tube and ovary", received fresh and placed in formalin is a 19.5 gram adnexal specimen consisting of a 1.5 x 1.5 x 0.4 cm presumed ovary with attached 4 x 3 x 2 cm exophytic tumor. A 3.5 x 0.2 cm fimbriated fallopian tube is identified. Representative tube and ovary submitted in block D1. Representative periadnexal tissue is submitted in block D2.

E. "Uterus", received fresh and placed in formalin is a 400 gram, 11 x 9 x 7 cm uterus with attached 4 cm cervix with 0.5 cm patent cervical os. The serosal surface is remarkable for a 5 x 4.5 x 3.5 cm attached calcified leiomyoma with numerous caked, white-tan possible tumor spreading a geographic distribution throughout. The endometrium is markedly distorted by multiple leiomyomata with no evidence of hemorrhage or necrosis. The endometrial surface demonstrates no evidence of thickening or mass lesion. The endometrium averages 0.1 cm thick and the myometrium averages 2.7 cm thick. Representative sections submitted as follows:

BLOCK SUMMARY:

- E1- anterior cervix
- E2- posterior cervix
- E3- endomyometrium
- E4- caked serosal thickening
- E5- calcified serosal leiomyoma

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- poorly differentiated carcinoma present

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY & OOPHORECTOMY & DEBULKING

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is

[page 2 of 2]
TCGA-29-1777

transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

C, D. "RIGHT AND LEFT OVARY":

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 2

TUMOR SIZE: 3 AND 4 CM, RESPECTIVELY.

WEIGHT: 26 AND 19 GRAMS, RESPECTIVELY

SEROA: INVOLVED WITH TUMOR

ADDITIONAL FINDINGS: NONE

WITH METASTATIC/IMPLANTED TUMOR, INVOLVING THE FOLLOWING SPECIMENS

A. OMENTUM

B. OMENTUM

C. RIGHT FALLOPIAN TUBE (MASSIVE IN LUMEN)

E. UTERUS, 400 GRAMS

SEROA: TUMOR WITH SUBSEROUSAL LYMPHATIC SPREAD

ENDOMETRIUM: QUIESCENT

MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS

CERVIX: NO PATHOLOGIC DIAGNOSIS

SPECIMENS FREE OF TUMOR

D. LEFT FALLOPIAN TUBE

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3f7974a3-be09-469a-8f56-889597aec920 (TCGA-29-1777.BFD59906-509B-4CA3-9282-C881F9962E15.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).